TARGET case TARGET-40-PASEHK — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b9e27be-b8f5-5cd2-985b-90ebfc726005

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.3; Tissue or organ of origin: Rib, sternum, clavicle and associated joints; Classification of tumor: primary; Age at diagnosis: 16.2 years (5,918 days); Year of diagnosis: 2008; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,791 days (4.9 years).
   Treatment given: Protocol identifier: AOST0331.

Follow-up (2 entries)
- Days to follow up: 1,330 days (3.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,330 days (3.6 years); Days to first event: 1,330 days (3.6 years); First event: Relapse.
- Days to follow up: 1,791 days (4.9 years); Year of follow up: 2013.

Biospecimens (1 sample)
- Sample TARGET-40-PASEHK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PASEHK-01A-01:
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 75
- % Non Tumor Nuclei: Top from Biopsy: 25
- % Cellular Tumor: Top from Biopsy: 35
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 60
- % Necrosis: Top from Biopsy: 5
- % Tumor Nuclei: Bottom from Biopsy: 95
- % Non Tumor Nuclei: Bottom from Biopsy: 5
- % Cellular Tumor: Bottom from Biopsy: 90
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 10
- PASS/FAIL: PASS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1791
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Other
- Specific tumor site: Ribs
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Lung
- Histologic response: Stage 1/2 (0-90 % necrosis)
